Gene-level copy-number profile of tumor specimen TCGA-F7-8298-01A from TCGA case TCGA-F7-8298, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 58.7 years (21,445 days).
Specimen TCGA-F7-8298-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.6c223645-f1c8-48e0-b481-466c29194c58.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F7-8298-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/61b6536f-d9f8-497b-8123-a4fec54633e8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 9,900; copy number 2: 46,581; copy number 3: 2,967; copy number 4: 246; copy number 5: 5; copy number 7: 1; copy number 8: 81.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F7-8298-01A-11D-2390-01): tumor purity 0.53, ploidy 2.11, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–21,995,301, 3 genes: ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr18:20,946,906–21,111,813, 1 gene (within-gene range 0–2): ROCK1.
- chr18:39,314,240–39,335,672, 2 genes: AC011139.1, RPL7AP66.
- chr18:80,034,346–80,097,088, 1 gene (within-gene range 0–3): AC090360.1.
- chr18:80,046,900–80,247,514, 7 genes (within-gene range 0–3): RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.
- chr21:10,328,411–10,649,835, 10 genes: AP003900.1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 87 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:69,303,412–69,303,807, 1 gene, copy number 7: IFITM9P.
- chr11:69,641,156–71,818,238, 64 genes, copy number 8 (within-gene range 1–8) (broad region; genes not listed).
- chr13:53,207,831–53,801,489, 5 genes, copy number 5 (within-gene range 2–5): AL356295.1, RN7SL618P, AL450423.2, AL450423.1, ZNF646P1.
- chr20:33,787,373–34,311,802, 17 genes, copy number 8: ZNF341-AS1, CHMP4B, TPM3P2, PIGPP3, RALY-AS1, RALY, AL031668.1, MIR4755, EIF2S2, RPS2P1, AL031668.2, ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2.

Autosomal genes at a single copy (total copy number 1): 7,522. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
